Somatic mutation profile of tumor specimen MP2PRT-PARWTE-TMP1-A (aliquot MP2PRT-PARWTE-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PARWTE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (608 days).
Specimen MP2PRT-PARWTE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f0eec7b-3a5b-4038-9551-a015ec19065d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARWTE-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARWTE-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbd7b484-d7c3-4428-878a-d7ed533b23b6

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LGALS9C | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 225/774 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs769945043; called by muse, mutect2, varscan2
- RFPL4AL1 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 208/506 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs578017434; called by muse, varscan2
- GLI2 | c.2729T>A p.L910Q (on ENST00000361492 / NM_001374353.1; = p.L927Q on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/1004 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.405); called by muse, mutect2
- TTN | c.50179C>G p.P16727A (on ENST00000591111; = p.P9303A on NM_003319.4) | Missense Mutation (SNP) | VAF 54/130 reads (42%) | PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ADAM11 | c.1593C>T p.D531= | Silent (SNP) | VAF 173/577 reads (30%) | catalogued as rs1185891749, COSV99567467; called by muse, mutect2, varscan2
- MAPT | c.1536C>T p.S512= (on ENST00000262410 / NM_001377265.1; = p.S437= on NM_016835.4) | Silent (SNP) | VAF 280/1032 reads (27%) | called by muse, mutect2, varscan2
- CD28 | chr2:203706586 C>G | 5'Flank (SNP) | VAF 256/636 reads (40%) | catalogued as COSV100142609; called by muse, mutect2, varscan2
